Surgical pathology report (de-identified scan), TCGA case TCGA-LP-A4AV, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site ILSBIO, specimen TCGA-LP-A4AV-01A (Primary Tumor).

[page 1 of 6]
Clinical Case Report

(For Collection of Cancerous Tissue)

ICD-0-3

carcinoma, squamous cell
keratinizing, NOS 8071/3

Site: cervix, NOS C53.9

lw 9/26/12

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
	153 cm	☐ Single ☒ Married	Vietnam	37°3
Gender	Weight	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
☐ Male ☒ Female	42 kg		180/110	80

HISTORY OF PRESENT ILLNESS	
Chief Complaints:	bleeding vagina
Symptoms:	abnormal bleeding vagina for 3 months
Clinical Findings:	- ulcer cervix - small uteri
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden	

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
NO				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 6]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status
normal			

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☒ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☒ IUD ☐ Other:		☐ Hormone Replacement Therapy: N/A

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis
normal		

LAB DATA					
Test	Result	Date	Test	Result	Date
HIV	☒ Negative ☐ Positive:		CEA	☐ Negative ☐ Positive:	
Hep B	☐ Negative ☐ Positive:		CA 15-3	☐ Negative ☐ Positive:	
Hep C	☐ Negative ☐ Positive:	N/A	CA 19-9	☐ Negative ☐ Positive:	N/A
AFP	☐ Negative ☐ Positive:		PSA	☐ Negative ☐ Positive:	
Other:	☐ Negative ☐ Positive:		Other:	☐ Negative ☐ Positive:	
B/T Cell Markers:					

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	normal	
X-Ray	normal	
CT	N/A	
Endoscopy	N/A	
MRI	N/A	
Biopsy	abnormal cells (cytology: Pap smear)	

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Cervical Cancer	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	
T N M	Stage: Ib
Date of Diagnosis	

Treatment Information

SURGICAL TREATMENT		
Procedure	Date of Procedure	
Radical Hysterectomy		
Primary Tumor		
Organ	Detailed Location	Size
Cervix	ulcer	2.5 x 1 x 1 cm
Extension of Tumor		
Endo cervix		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes	N/A	N/A
Dissected Lymph Nodes	para-aortic nodes	3
Distant Metastasis		
Organ	Detailed Location	Size
NO		
Surgical Staging		
T N M	Stage: Ib	

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
NO				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 6]
Pathology Form

Specimen Information

Collected by: _

Date: .

Time: _

Preserved by: _

Date: _

Time: _

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
						3	1
Time to LN2		Time to Formalin		Time to LN2			
9 min		12 min		6 min			

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
cervix	2.5 x 1 x 1 cm	Endo-cervix	0.3 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
para-aortic nodes	3	0	
Distant Metastasis			
Organ	Detailed Location	Size	
u/k	u/k	u/k	
Pathological Staging			
pT	N	M	Stage: u Ib
Notes:			

[page 5 of 6]
Microscopic Description

Histological Pattern												
Cell Distribution				Structural Pattern								
Diffuse	+	-		Streaming				+				-
Mosaic				Storiform				+				
Necrosis	+			Fibrosis								-
Lymphocytic Infiltration	+			Pallisading								
Vascular Invasion			-	Cystic Degeneration								
Clusterized	+			Bleeding								
Alveolar Formation			-	Myxoid Change								
Indian File			-	Psammoma/Calcification								
Cellular Differentiation												
Squamous			Adenomatous			Sarcomatous			Lymphomatous			
Squamoid Cell	+	-	Glandular cell	+	-	Round Cell	+	-	Large Cell	+	-	
Spindle Cell		-	Cell Stratification		-	Fibroblast		-	Small Cell		-	
Keratin	+		Secretion		-	Osteoblast		-	RS Cell/RS Like		-	
Desmosome	+		Intracyt. Vacuole		-	Lipoblast		-	Inflam. Cell	+		
Pearl	+		Gland formation		-	Myoblast		-	Plasma Cell	+		
Cellular Differentiation: Well + Moderate Poor												
Nuclear Appearance												
Nuclear Atypia:						0	I	II	III			
Aniso Nucleosis							+					
Hyperchromatism												
Nucleolar Prominent								+				
Multinucleated Giant Cell								+				
Mitotic Activity						+						
Nuclear Grade:							+					

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive	N/A	
PR	☐ Negative ☐ Positive	N/A	
Her-2/neu	☐ Negative ☐ Positive	N/A	
B-Cell Marker	☐ Negative ☐ Positive	N/A	
T-Cell Marker	☐ Negative ☐ Positive	N/A	
Other:	☐ Negative ☐ Positive	N/A	
Other:	☐ Negative ☐ Positive	N/A	

Final Pathology Report

Histological Diagnosis: Keratinizing Squamous cell carcinoma **Grade:** I

Comments:

Principal Investigator

Pathologist

Date

[page 6 of 6]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse		✓	Streaming		
Mosaic	✓		Storiform		
Necrosis		✓	Fibrosis		
Lymphocytic Infiltration	✓		Palisading		
Vascular Invasion		✓	Cystic Degeneration		
Clusterized	✓		Bleeding		
Alveolar Formation		✓	Myxoid Change		
Indian File		✓	Psammoma/Calcification		

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell	✓		Glandular cell			Round Cell			Large Cell		
Spindle Cell	✓		Cell Stratification			Fibroblast			Small Cell		
Keratin	✓		Secretion			Osteoblast			RS Cell/RS Like		
Desmosome	✓		Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl	✓		Gland formation			Myoblast			Plasma Cell		

Otherwise Specified:

D1 70% D2 50% D3 30%

2. Cellular Differentiation:

Well	Moderately	Poor
	✓	

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis			✓	
Hyperchromatism			✓	
Nucleolar Prominent			✓	
Multinucleated Giant Cell			✓	
Mitotic Activity			✓	
Nuclear Grade				

Histological Diagnosis: Squamous cell carcinoma, G2

Comments: _____

Date

Director, Research Pathology

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

IHPAA Discrepancy		✓

Source: NCI Genomic Data Commons file b889efb8-8191-446e-acd4-9d1148ddf895 (TCGA-LP-A4AV.7880E0A0-01B8-4A31-967D-8833B20752BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).